Somatic mutation profile of tumor specimen TCGA-06-A7TL-01A (aliquot TCGA-06-A7TL-01A-11D-A391-08) from TCGA case TCGA-06-A7TL, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 30.9 years (11,297 days).
Specimen TCGA-06-A7TL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ab07fdf2-e02f-4e37-a0d6-0c42813c3a92.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-A7TL-10A (Blood Derived Normal), aliquot TCGA-06-A7TL-10A-01D-A394-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/00a6589b-6c02-4b41-b363-fb5e7151675b

The open-access MAF lists 29 somatic variants for this specimen: 22 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 6, Nonsense Mutation 2, In Frame Del 2, 3'UTR 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 16/59 reads (27%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.824G>A p.C275Y | Missense Mutation (SNP) | VAF 15/20 reads (75%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs863224451, CM076568, CM951234, COSV52661919, COSV52663595, COSV52675710, COSV52772708; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- ALPI | c.1294G>A p.E432K | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT tolerated (0.13); PolyPhen benign (0.006); catalogued as rs200399293, COSV55015166; called by muse, mutect2, varscan2
- ATRX | c.4084G>T p.E1362* | Nonsense Mutation (SNP) | VAF 23/88 reads (26%) | catalogued as COSV100970289; called by muse, mutect2, varscan2
- FOXR1 | c.502G>A p.G168R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT tolerated (0.74); PolyPhen probably damaging (0.992); catalogued as COSV100392845; called by muse, mutect2, varscan2
- FRMPD4 | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 56/102 reads (55%) | SIFT deleterious (0); PolyPhen possibly damaging (0.634); catalogued as rs1322816860, COSV101042446; called by muse, mutect2, varscan2
- KCNU1 | c.422T>C p.I141T | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as rs1363072702, COSV101299044; called by muse, mutect2, varscan2
- KIAA1614 | c.1885G>A p.G629R | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.28); PolyPhen benign (0.121); catalogued as COSV100851169; called by muse, mutect2, varscan2
- LPAR3 | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 80/237 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762836142, COSV101004705; called by muse, mutect2, varscan2
- LRBA | c.2022A>C p.E674D | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.989); catalogued as COSV100841141; called by muse, mutect2, varscan2
- MUC2 | c.2571G>A p.P857= | Splice Region (SNP) | VAF 4/30 reads (13%) | catalogued as rs372557359; called by muse, mutect2, varscan2
- MYO15A | c.1340G>A p.G447E | Missense Mutation (SNP) | VAF 20/42 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.079); catalogued as rs1189542254, COSV99231695; called by muse, mutect2, varscan2
- NRG1 | c.173A>T p.Y58F (on ENST00000523534; = p.Y205F on NM_013962.2) | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV101584765, COSV73057593; called by muse, mutect2, varscan2
- OXR1 | c.751G>T p.V251F (on ENST00000442977 / NM_001198532.1; = p.V250F on NM_018002.3) | Missense Mutation (SNP) | VAF 15/42 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760500916, COSV100366988; called by muse, mutect2, varscan2
- SLC22A16 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (0.6); PolyPhen benign (0.031); catalogued as rs779431283, COSV100397298; called by muse, mutect2, varscan2
- SUGCT | c.1196G>T p.R399M (on ENST00000335693 / NM_001193313.2; = p.R425M on NM_024728.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT tolerated (0.15); PolyPhen benign (0.019); catalogued as COSV100000648; called by muse, mutect2, varscan2
- TNFAIP2 | c.1277T>C p.I426T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as COSV100280866; called by muse, mutect2, varscan2
- TPO | c.2354A>G p.E785G | Missense Mutation (SNP) | VAF 17/50 reads (34%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV100220225; called by muse, mutect2, varscan2
- ZNF639 | c.1111A>T p.K371* | Nonsense Mutation (SNP) | VAF 16/58 reads (28%) | catalogued as COSV100418397; called by muse, mutect2, varscan2
- ZNF671 | c.1190A>T p.Y397F | Missense Mutation (SNP) | VAF 18/54 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.068); catalogued as COSV100234898; called by muse, mutect2, varscan2
- ATP8B1 | c.1039_1041del p.V347del | In Frame Del (DEL) | VAF 6/23 reads (26%) | called by pindel, varscan2
- BEX1 | c.155_169del p.R52_R56del | In Frame Del (DEL) | VAF 26/111 reads (23%) | called by pindel, varscan2
- ARG1 | c.648C>G p.L216= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as COSV99256030; called by muse, mutect2, varscan2
- MTM1 | c.1020T>C p.S340= | Silent (SNP) | VAF 43/103 reads (42%) | catalogued as COSV100080288; called by muse, mutect2, varscan2
- SPATA31D1 | c.786T>A p.P262= | Silent (SNP) | VAF 93/284 reads (33%) | catalogued as COSV100782603; called by muse, mutect2, varscan2
- SPTBN2 | c.624A>G p.G208= | Silent (SNP) | VAF 41/91 reads (45%) | catalogued as COSV100018592; called by muse, mutect2, varscan2
- TBC1D24 | c.36A>G p.K12= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs752594126, COSV99564797; called by muse, mutect2, varscan2
- TEX35 | c.511C>T p.L171= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs750003333, COSV51102956; called by muse, mutect2, varscan2
- LARS2 | c.*161C>G | 3'UTR (SNP) | VAF 22/43 reads (51%) | catalogued as COSV55527793, COSV99647537; called by muse, mutect2, varscan2
